Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A3C7, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A3C7-06A (Metastatic).

[page 1 of 2]
DIAGNOSIS:

Patient ID -

- (A) KNEE, LEFT, SKIN ELLIPSE:
Seborrheic keratosis, tissue edges appear free.
- (B) KNEE, RIGHT, SKIN ELLIPSE:
Seborrheic keratosis, tissue edges appear free.
- (C) CLOQUET'S NODE, EXCISION:
One lymph node(s), negative for malignancy (0/1).
- (D) LYMPH NODES, LEFT INGUINAL, EXCISION:
MELANOMA, METASTATIC TO ONE OF TWELVE LYMPH NODES (1/12).
Largest tumor deposit size: 30.0 MM (PER GROSS REPORT).
Location: Subcapsular and intraparenchymal.
Extracapsular extension: not identified.
- (E) LYMPH NODES, LEFT COMMON ILIAC, EXCISION:
Three lymph node(s), negative for malignancy (0/3).
- (F) LYMPH NODES, LEFT EXTERNAL ILLIAC, EXCISION:
Eleven lymph node(s), negative for malignancy (0/11).
- (G) LYMPH NODES, OBTURATOR, EXCISION:
Nine lymph node(s), negative for malignancy (0/9).

1CD-0-3

Melanoma, NOS 8720/3

Site: lymph node, inguinal

C77.4
pw
10/3/11

GROSS DESCRIPTION

- (A) LEFT LATERAL KNEE MASS - A 0.4 x 0.4 x 0.2 cm punch of soft, white-pink tissue which is submitted in toto as A.
- (B) RIGHT LATERAL KNEE MASS - A 0.6 x 0.6 x 0.6 punch of skin with attached soft tissue. The edge of the specimen is inked blue and the specimen is bisected and submitted in toto as B.
- (C) CLOQUET'S NODE - A 1.5 x 1.4 x 0.7 cm lymph node with a scanty amount of attached adipose tissue. The lymph node is unremarkable. The lymph node is sectioned and submitted in toto with the adjacent adipose tissue in one cassette labeled as C.
- (D) LEFT INGUINAL NODE - Received is one fragment of fibroadipose tissue (18 x 8 x 2.5 cm) with twelve possible lymph nodes, the largest of which measures 4 cm in greatest dimension. The largest lymph node is positive for metastasis, 3 cm in greatest dimension.

Tumor was submitted to tissue bank and for the TIL protocol.

SECTION CODE: D1, D2, representative section of largest positive lymph node; D3, D4, one lymph node, serially sectioned; D5-D7, one lymph node, serially sectioned; D8, D9, one lymph node, serially sectioned; D10-D12, one lymph node, serially sectioned; D13-D19, one lymph node, serially sectioned per cassette.

(E) LEFT COMMON ILIAC NODES - Two irregularly-shaped fragments of soft, yellow-red tissue ranging in size from the smallest measuring 1.5 cm in greatest dimension to the largest measuring 4.5 cm in greatest dimension. Each fragment contains an unremarkable lymph node.

SECTION CODE: E1, one lymph node section; E2, one lymph node section; E3, E4, one lymph node section. The lymph nodes have been submitted in toto.

(F) LEFT EXTERNAL ILIAC NODES - A 7 x 4 x 1.2 cm piece of adipose tissue containing four lymph nodes ranging in size from the largest measuring 4.5 cm to the smallest measuring 2 cm in greatest dimension.

SECTION CODE: F1, one lymph node section in multiple pieces; F2, F3, a single lymph node section; F4-F6, one lymph node, serially sectioned; F7-F14, one lymph node, serially sectioned per cassette. Lymph nodes have been submitted in toto.

(G) OBTURATOR NODES - A 17 x 4 x 1.5 cm irregularly-shaped piece of adipose tissue. The specimen contains multiple lymph nodes ranging in size from the smallest measuring 0.3 cm in greatest dimension to the largest measuring 5.4 cm in greatest dimension.

SECTION CODE: G1, one lymph node, bisected; G2, one lymph node, bisected; G3, one lymph node, bisected; G4, two lymph nodes, one bisected; G5, one apparent lymph node, bisected; G6-G8, a single lymph node section. All lymph nodes have been submitted in toto.

CLINICAL HISTORY

None given.

SNOMED CODES

	10/3/11	

[page 2 of 2]
M-72750 M-72750 M-00110 M-87206 M-00110 M-00110
M-00110

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration.*

These tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Source: NCI Genomic Data Commons file 746193f8-64c4-4b27-8f5d-69f7b7ebf790 (TCGA-D3-A3C7.9FABC766-7052-4352-8DC7-5160C9D768AB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).